Gene-level copy-number profile of tumor specimen BLGSP-71-30-00666-01A from CGCI case BLGSP-71-30-00666, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 49.9 years (18,234 days).
Specimen BLGSP-71-30-00666-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Small Bowel; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ddd03f8f-a4d0-464b-9cd5-b26e6b978f07.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-30-00666-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,800 have no estimate.
https://portal.gdc.cancer.gov/files/0d260202-707d-4204-b60c-01bc9188418c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 4,475; copy number 2: 48,150; copy number 3: 5,369; copy number 4: 727; copy number 5: 66; copy number 6: 10; copy number 7: 17; copy number 11: 3; copy number 13: 1; copy number 29: 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,036,958–130,038,422, 1 gene (within-gene range 0–2): KLF2P1.
- chr9:61,642,383–61,662,690, 2 genes: Y_RNA, AL935212.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 99 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,449,689–1,470,163, 1 gene, copy number 5: ATAD3C.
- chr1:235,328,570–235,448,952, 1 gene, copy number 5 (within-gene range 3–5): AL357556.3.
- chr1:235,361,153–235,452,443, 3 genes, copy number 5 (within-gene range 3–5): AL357556.1, AL357556.5, TBCE.
- chr2:25,697,076–25,697,188, 1 gene, copy number 6: Y_RNA.
- chr2:97,281,356–97,291,849, 1 gene, copy number 5: AC159540.2.
- chr3:48,917,782–48,918,823, 1 gene, copy number 7 (within-gene range 3–7): ARIH2OS.
- chr7:5,925,550–5,970,683, 1 gene, copy number 5 (within-gene range 2–5): RSPH10B.
- chr7:62,275,361–62,275,678, 1 gene, copy number 5: AC128676.1.
- chr7:73,593,194–73,624,543, 2 genes, copy number 5: MLXIPL, AC005089.1.
- chr7:73,861,159–73,865,890, 1 gene, copy number 5: TMEM270.
- chr7:100,572,228–100,608,175, 6 genes, copy number 5 (within-gene range 4–5): SAP25, AC069281.2, LRCH4, FBXO24, PCOLCE-AS1, PCOLCE.
- chr7:101,195,007–101,204,495, 3 genes, copy number 5: MOGAT3, DGAT2L7P, RPSAP46.
- chr7:101,269,938–101,273,715, 2 genes, copy number 5: RNU6-1104P, AC006329.1.
- chr9:40,481,558–40,642,117, 6 genes, copy number 7: AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2.
- chr9:64,810,865–64,811,429, 1 gene, copy number 6: BNIP3P4.
- chr9:65,189,995–65,285,209, 4 genes, copy number 6–13: BMS1P12, AL512605.1, AL512605.2, FOXD4L5.
- chr11:48,589,760–48,908,946, 7 genes, copy number 5–6: OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr12:14,356,842–14,365,503, 1 gene, copy number 5: RPL30P11.
- chr12:37,575,587–37,576,384, 1 gene, copy number 5: ZNF970P.
- chr12:111,599,498–111,600,256, 1 gene, copy number 5 (within-gene range 3–5): ATXN2-AS.
- chr15:40,686,183–40,755,851, 3 genes, copy number 5: RAD51-AS1, RAD51, RMDN3.
- chr16:21,796,106–21,820,410, 1 gene, copy number 5: RRN3P1.
- chr16:30,989,256–31,049,868, 3 genes, copy number 5–6: STX1B, STX4, AC135050.3.
- chr16:33,533,816–33,570,935, 4 genes, copy number 7: AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr16:33,802,764–33,810,767, 2 genes, copy number 29: IGHV3OR16-12, AC136428.3.
- chr16:33,907,419–33,937,167, 1 gene, copy number 5: ARHGAP23P1.
- chr17:43,216,941–43,305,397, 14 genes, copy number 5 (within-gene range 3–5): CCDC200, RNU2-1, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2.
- chr17:75,751,594–75,785,893, 3 genes, copy number 5 (within-gene range 2–5): GALK1, H3-3B, MIR4738.
- chr19:10,289,952–10,339,661, 8 genes, copy number 5: ICAM5, ZGLP1, AC011511.1, FDX2, AC011511.4, RAVER1, AC114271.1, ICAM3.
- chr19:17,390,509–17,418,288, 3 genes, copy number 5 (within-gene range 4–5): CCDC194, BST2, AC010319.1.
- chr19:44,954,585–44,993,341, 1 gene, copy number 5: CLPTM1.
- chr21:44,172,169–44,194,338, 2 genes, copy number 5: AP001056.2, AP001056.1.
- chr21:44,217,014–44,244,993, 3 genes, copy number 11: ICOSLG, AP001059.2, AP001059.1.
- chr22:21,341,595–21,345,258, 1 gene, copy number 7: PPP1R26P5.
- chr22:21,379,382–21,396,590, 5 genes, copy number 7: Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 1,780. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
